Surgical pathology report (de-identified scan), TCGA case TCGA-SB-A76C, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Baylor College of Medicine, specimen TCGA-SB-A76C-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Results

Entry Date _____

Component Results

NOTE:

SURGICAL PATHOLOGY REPORT

Corrected

Status: Signed Out

Date of Service: _____

This corrected report is issued to address a typographical error in the tumor synopsis. No other changes were made.

MICROSCOPIC DIAGNOSIS:

LEFT TESTIS, MASS, RADICAL ORCHIECTOMY:
CLASSIC SEMINOMA, CONFINED TO THE TESTIS
SEE DETAILS BELOW

Per TSS - 100% pure/classic
Seminoma

BCR

Tumor Synopsis:

Tumor Site: Left.

Tumor Focality: Unifocal.

Tumor Size: 4.0 cm in greatest dimension.

Macroscopic Extent of tumor: Tumor confined to the testis.

Histologic Type: Classic seminoma.

Margins:

Spermatic Cord Margin: No tumor identified.

Microscopic Tumor Extension: The tumor is confined to the testis. No invasion into

epididymis is seen. The tumor abuts the rete testis. No definite invasion is seen.

Lymph-vascular Invasion: Not identified.

TNM Designation:

pT1

pNX

pM not applicable

Regional Lymph Nodes:

Number examined: Not sampled.

Additional Pathologic Findings:

Intratubular germ cell neoplasia.

Testicular microlithiasis.

ICD-O-3

Seminoma NOS 9061/3

Site Testis NOS C62.9

JUN 8/22/13

Pathologist

CLINICAL HISTORY:

Left testicular mass

SPECIMEN SOURCE:

Left testicle

GROSS DESCRIPTION:

Specimen 1, received in formalin designated "left testicle" is a radical orchiectomy specimen, including the left testis (6 x 4 x 3.5 cm), epididymis (3.5 x 1.0 x 1.0 cm), and spermatic cord (6.5 x 1.5 x 1.0 cm).

[page 2 of 2]
[REDACTED]

There is a 4 x 3.5 x 3.0 cm well-circumscribed, tan-white lobulated tumor within the testis. The cut surface of the tumor has a glistening gray-white appearance, with minimal hemorrhage. The tumor is confined to the testis, without gross involvement of the tunica albuginea, epididymis, or spermatic cord.

The testicular parenchyma at the edge of the tumor is compressed, and is grossly unremarkable. Serial sections of the epididymis and spermatic cord show no focal lesions. The spermatic cord surgical margin on gross examination is free of tumor.

Ink Code: Black - external surface of testis and spermatic cord.

Section Code: A1, spermatic cord margin of resection en face; A2-A5, representative sections of tumor with relationship to epididymis (head and body of epididymis); A6-A7, representative tumor, with closest association to tunica albuginea; A8-A9, representative tumor to uninvolved testis; representative sections of uninvolved testis; A11-A12, representative sections of spermatic cord from distal to proximal.

Performed at:

--Electronically Signed Out by

Lab and Collection

SURGICAL PATHOLOGY REPORT on

Result History

SURGICAL PATHOLOGY REPORT on

Status:

This result is currently shared in

Last viewed in

By:

Printer Friendly Report

SURGICAL PATHOLOGY RE

Lab Information

Lab

Result Report

Patient imaging report

HIFAA Discrepancy		

**SURGICAL PATHOLOGY
REPORT**

Authorizing:

Date:

Printed by

Source: NCI Genomic Data Commons file 7af72214-1fe7-4fc6-bcd3-0b2c5acd196f (TCGA-SB-A76C.18775FB4-5DD0-475B-A648-D6A3E178B2D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).